Somatic mutation profile of tumor specimen TCGA-BR-8486-01A (aliquot TCGA-BR-8486-01A-31D-2394-08) from TCGA case TCGA-BR-8486, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-BR-8486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a013b0d8-6b68-4082-a36a-d4684aaec93b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8486-10A (Blood Derived Normal), aliquot TCGA-BR-8486-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da0f8add-b36c-4514-9211-cd6d8f740e8f

The open-access MAF lists 60 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 10, Splice Site 3, Frame Shift Ins 2, In Frame Del 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6AP2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs1057523485, COSV65798266; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.7858G>C p.E2620Q (on ENST00000359028; = p.E2596Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.337); catalogued as COSV62338489, COSV62356557; called by muse, mutect2, varscan2
- ARHGAP6 | c.2723C>T p.T908M (on ENST00000337414 / NM_013427.3; = p.T705M on NM_013423.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.036); catalogued as rs768446501, COSV57302515; called by muse, mutect2, varscan2
- CARD11 | c.2662C>T p.R888C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs142828146, COSV62753932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEND1 | c.124_126del p.K42del | In Frame Del (DEL) | VAF 36/139 reads (26%) | catalogued as rs769506630; called by pindel, varscan2
- CHRNB4 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55718077; called by muse, mutect2, varscan2
- CHST7 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.61); catalogued as rs371271901, COSV52101177; called by muse, mutect2, varscan2
- DNPEP | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs555897972, COSV56111840; called by muse, mutect2, varscan2
- EYA3 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs199531017, COSV65815442; called by muse, mutect2, varscan2
- FAM117A | c.1214C>G p.P405R | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53604130; called by muse, mutect2, varscan2
- GMIP | c.1406A>C p.D469A | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV52559550; called by muse, mutect2, varscan2
- GPC4 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1353328059, COSV63697323; called by muse, mutect2, varscan2
- GTF2IRD1 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs782623972, COSV56091333; called by muse, mutect2, varscan2
- HEPH | c.412+1G>A p.X138_splice (on ENST00000343002; = p.X192_splice on NM_138737.5) | Splice Site (SNP) | VAF 22/158 reads (14%) | catalogued as COSV57971114; called by muse, mutect2, varscan2
- HMCN1 | c.13829C>T p.T4610I | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV54936081; called by muse, mutect2, varscan2
- HYDIN | c.13937C>T p.T4646M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1274466233; called by muse, varscan2
- HYDIN | c.205A>C p.M69L | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV55497230; called by muse, mutect2
- IL13 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV58734621; called by muse, mutect2, varscan2
- KCNJ11 | c.1123A>G p.M375V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777540229, COSV60594783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK13 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs547806943, COSV56417066; called by muse, mutect2, varscan2
- MTM1 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV60337394; called by muse, mutect2
- MYEF2 | c.1625A>T p.K542I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV51052372; called by muse, mutect2, varscan2
- MYT1 | c.1876G>T p.A626S | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV60505561, COSV60512364; called by muse, mutect2, varscan2
- ORM1 | c.329-2A>T p.X110_splice | Splice Site (SNP) | VAF 17/44 reads (39%) | catalogued as rs112963597, COSV52280985; called by muse, mutect2, varscan2
- PAX9 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as COSV64062407; called by muse, mutect2, varscan2
- PCDH11X | c.3845G>C p.W1282S | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.676); catalogued as COSV53499761; called by muse, mutect2
- PCLO | c.7651G>A p.D2551N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as rs752052300, COSV61661830; called by muse, mutect2, varscan2
- PGRMC1 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs769632512, COSV54293545; called by muse, mutect2, varscan2
- PKHD1 | c.3110C>A p.A1037D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV61892460; called by muse, mutect2, varscan2
- PPIG | c.2072A>G p.K691R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53645709; called by muse, mutect2, varscan2
- PRKCQ | c.1136A>G p.D379G | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV54118192; called by muse, mutect2, varscan2
- PRKD1 | c.2434G>T p.A812S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV59583917; called by muse, mutect2
- SARDH | c.2623G>A p.G875S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs760438211, COSV64100968; called by muse, mutect2, varscan2
- SCN1A | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1266240114, COSV57684963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SND1 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as rs773076395, COSV61234632, COSV61248088; called by muse, mutect2, varscan2
- SNRNP200 | c.4346A>G p.N1449S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs575003767, COSV60493999; called by muse, mutect2, varscan2
- ST8SIA6 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV66471484; called by muse, mutect2, varscan2
- STAG1 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52602021; called by muse, mutect2, varscan2
- STAT1 | c.1221+2T>C p.X407_splice | Splice Site (SNP) | VAF 18/264 reads (7%) | catalogued as COSV63117292; called by muse, mutect2
- STRN | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as COSV55751680; called by muse, mutect2, varscan2
- TENM1 | c.4198G>A p.A1400T | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64441469; called by muse, mutect2, varscan2
- THSD4 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377159901; called by muse, mutect2, varscan2
- TP53 | c.291_292insG p.P98Afs*51 | Frame Shift Ins (INS) | VAF 46/108 reads (43%) | catalogued as COSV52928135; called by mutect2, pindel, varscan2
- UBR5 | c.6809_6810insTA p.P2271Nfs*8 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | catalogued as COSV99638808; called by mutect2, pindel, varscan2
- ZNF3 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1350929811, COSV52795640, COSV52796445; called by muse, mutect2, varscan2
- ZSCAN2 | c.874A>C p.N292H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV57572647; called by muse, mutect2, varscan2
- HECTD1 | c.7204_7209del p.P2402_L2403del | In Frame Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- NSD1 | c.4595A>T p.Q1532L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); called by muse, mutect2
- TMPRSS7 | c.2006G>A p.G669E (on ENST00000452346; = p.G543E on NM_001042575.2) | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADD1 | c.606A>G p.L202= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs746215398; called by muse, mutect2, varscan2
- GTF2IRD1 | c.120C>A p.S40= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV56091326, COSV56092897; called by muse, mutect2, varscan2
- HOXA6 | c.660G>A p.T220= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV56074624; called by muse, mutect2
- IGHV3-74 | c.249G>A p.V83= | Silent (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- KCNB1 | c.1794C>T p.F598= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV65570592; called by muse, mutect2, varscan2
- KCNB1 | c.1635C>G p.L545= | Silent (SNP) | VAF 110/224 reads (49%) | catalogued as COSV65570597; called by muse, mutect2, varscan2
- NEK8 | c.465C>T p.S155= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV52048426; called by muse, mutect2, varscan2
- RCSD1 | c.1008A>C p.T336= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV63260812; called by muse, mutect2, varscan2
- SCAMP5 | c.180G>A p.A60= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs182851388, COSV62644095; called by muse, mutect2, varscan2
- WDR6 | c.2766G>A p.E922= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV58247238; called by muse, mutect2, varscan2
- H3C2 | c.-2C>T | 5'UTR (SNP) | VAF 55/129 reads (43%) | catalogued as rs146176019; called by muse, mutect2, varscan2
